Somatic mutation profile of tumor specimen TCGA-09-2043-01A (aliquot TCGA-09-2043-01A-01W-0799-08) from TCGA case TCGA-09-2043, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 69.8 years (25,480 days).
Specimen TCGA-09-2043-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb5ffed5-6ed5-4b22-8196-3b2650ea94cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2043-11A (Solid Tissue Normal), aliquot TCGA-09-2043-11A-01D-0704-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd071480-970c-48d0-a35e-f2c3d11a89c1

The open-access MAF lists 108 somatic variants for this specimen: 87 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 17, Frame Shift Ins 5, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 4, RNA 2, Intron 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.5153G>A p.W1718* | Nonsense Mutation (SNP) | VAF 80/100 reads (80%) | catalogued as rs41293461, CM041711, CM133532, CM980232, COSV100525043, COSV58800644; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.724T>C p.C242R | Missense Mutation (SNP) | VAF 588/778 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519982, CM107067, COSV52660956, COSV52677021, COSV52760397, COSV52839973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 512/579 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs762942384, COSV58643417; called by muse, mutect2, varscan2
- ACSM2B | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 64/1096 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100313116; called by muse, mutect2
- ADAM22 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs773425018, COSV99718276; called by muse, mutect2, varscan2
- ADCY8 | c.3103A>T p.T1035S | Missense Mutation (SNP) | VAF 398/1136 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99654275; called by muse, mutect2, varscan2
- ANGPT2 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 148/194 reads (76%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.638); catalogued as rs748039365, COSV100291181; called by muse, mutect2, varscan2
- ANO4 | c.1048T>C p.Y350H (on ENST00000392977 / NM_001286615.2; = p.Y315H on NM_178826.4) | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100153787; called by muse, mutect2
- APOB | c.13066C>G p.L4356V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.178); catalogued as COSV51947151, COSV99267992; called by muse, mutect2, varscan2
- AUTS2 | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100719527; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 56/342 reads (16%) | catalogued as rs745882580; called by mutect2, varscan2
- BSN | c.4334C>G p.A1445G | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99609790; called by muse, mutect2
- CARD6 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 412/1007 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99621295; called by muse, mutect2, varscan2
- COG5 | c.2295C>A p.D765E (on ENST00000347053 / NM_001379512.1; = p.D786E on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV99773158; called by muse, mutect2, varscan2
- COL11A1 | c.1558C>A p.L520I | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100617651; called by muse, mutect2, varscan2
- DNAH11 | c.5898T>G p.H1966Q | Missense Mutation (SNP) | VAF 90/516 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100180805; called by muse, mutect2, varscan2
- ELK4 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99222520; called by muse, mutect2, varscan2
- F8 | c.4430A>C p.E1477A | Missense Mutation (SNP) | VAF 274/970 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as CD141477, COSV100811931; called by muse, mutect2, varscan2
- FBXW8 | c.915C>A p.Y305* (on ENST00000309909; = p.Y343* on NM_012174.1) | Nonsense Mutation (SNP) | VAF 180/440 reads (41%) | catalogued as COSV99998001; called by muse, mutect2, varscan2
- FNTB | c.1047dup p.L350Afs*4 | Frame Shift Ins (INS) | VAF 16/115 reads (14%) | catalogued as rs768774237; called by mutect2, varscan2
- FSIP2 | c.17368G>A p.V5790I | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.323); catalogued as COSV100556480; called by muse, mutect2, varscan2
- GABRB1 | c.546T>G p.Y182* | Nonsense Mutation (SNP) | VAF 82/136 reads (60%) | catalogued as COSV99783445; called by muse, mutect2, varscan2
- GCM1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99452656; called by muse, mutect2, varscan2
- HS3ST2 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 483/1848 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99758568; called by muse, mutect2, varscan2
- HYAL1 | c.194C>G p.T65S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99807885; called by muse, mutect2, varscan2
- IGSF21 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 242/339 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs752370692, COSV52130811; called by muse, mutect2, varscan2
- IRAG1 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101351699; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 40/312 reads (13%) | catalogued as rs780982673; called by mutect2, varscan2
- KDM1A | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 336/800 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs199943849, COSV100752828; called by muse, mutect2, varscan2
- KIT | c.1914G>A p.M638I | Missense Mutation (SNP) | VAF 237/323 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99855305; called by muse, mutect2, varscan2
- LAT | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV100209279; called by muse, mutect2, varscan2
- LDLR | c.851G>A p.C284Y | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM045063, COSV99370305; called by muse, mutect2, varscan2
- MAGEA10 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 195/687 reads (28%) | catalogued as COSV99726920; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 11/83 reads (13%) | catalogued as rs765962881; called by mutect2, varscan2
- MCFD2 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 149/771 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs774183668, COSV100109182; called by muse, mutect2, varscan2
- METTL7A | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 223/646 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV100153725; called by muse, mutect2, varscan2
- MS4A5 | c.339+1G>T p.X113_splice | Splice Site (SNP) | VAF 18/28 reads (64%) | catalogued as COSV100281117; called by muse, mutect2, varscan2
- MST1R | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56565776, COSV99619670; called by muse, mutect2, varscan2
- NCDN | c.1720C>A p.L574I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100622177; called by muse, mutect2, varscan2
- NF1 | c.8447G>C p.G2816A (on ENST00000358273 / NM_001042492.3; = p.G2795A on NM_000267.3) | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100648233; called by muse, mutect2, varscan2
- NLRP9 | c.1409T>C p.I470T | Missense Mutation (SNP) | VAF 376/1365 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1253824584, COSV100243438; called by muse, mutect2, varscan2
- NPHP1 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV57212510; called by muse, mutect2
- OR2W1 | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 41/987 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV101013944; called by muse, mutect2
- OR51G2 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV100432239; called by muse, mutect2, varscan2
- PDE6H | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 65/473 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.547); catalogued as COSV99844062; called by muse, mutect2, varscan2
- PIGO | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99956948; called by muse, mutect2, varscan2
- PLEKHG6 | c.2135C>A p.S712* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV99164963; called by muse, mutect2, varscan2
- POLL | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1317279404, COSV100150466; called by muse, mutect2, varscan2
- POM121L12 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 14/361 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.422); catalogued as COSV68694200; called by muse, mutect2
- PPM1J | c.1481T>A p.F494Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.141); catalogued as COSV99588502; called by muse, mutect2, varscan2
- PROK2 | c.352A>G p.T118A (on ENST00000295619 / NM_001126128.2; = p.T97A on NM_021935.4) | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as COSV99817077; called by muse, mutect2, varscan2
- PRRC2B | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 206/599 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs375065861, COSV61935765; called by muse, mutect2, varscan2
- RAB3B | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 125/235 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100784875; called by muse, mutect2, varscan2
- RILPL1 | c.652C>G p.Q218E | Missense Mutation (SNP) | VAF 255/587 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV100526219; called by muse, mutect2, varscan2
- RMND5A | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV52154196, COSV99373959; called by muse, mutect2
- RPA2 | c.629A>T p.N210I | Missense Mutation (SNP) | VAF 144/392 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV100536302; called by muse, mutect2, varscan2
- SEZ6L | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 157/437 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs149306304; called by muse, mutect2, varscan2
- SLC2A14 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100534024; called by mutect2, varscan2
- SLC2A3 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 38/674 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99306929; called by muse, mutect2
- SLC35D3 | c.143C>G p.T48S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100090721; called by muse, mutect2, varscan2
- SLC4A5 | c.590A>T p.D197V | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.751); catalogued as COSV100698011; called by muse, mutect2, varscan2
- SMC6 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV100705343; called by muse, mutect2, varscan2
- STAT4 | c.448A>T p.I150F | Missense Mutation (SNP) | VAF 96/1083 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as COSV100636214, COSV61829574; called by muse, mutect2
- TDRD1 | c.3353T>A p.F1118Y | Missense Mutation (SNP) | VAF 275/1041 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99315118; called by muse, mutect2, varscan2
- TEX15 | c.4488C>G p.I1496M (on ENST00000256246; = p.I1879M on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs1401701830, COSV56354455, COSV99822102; called by muse, mutect2
- THSD7A | c.339A>T p.K113N | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV101448894; called by muse, mutect2, varscan2
- TTBK1 | c.2708G>T p.G903V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99445542; called by muse, mutect2, varscan2
- TTN | c.46111C>T p.L15371F (on ENST00000591111; = p.L7947F on NM_003319.4) | Missense Mutation (SNP) | VAF 154/697 reads (22%) | PolyPhen probably damaging (0.999); catalogued as COSV100613053; called by muse, mutect2, varscan2
- UBA6 | c.2954T>C p.M985T | Missense Mutation (SNP) | VAF 232/490 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100451885; called by muse, mutect2, varscan2
- UBOX5 | c.269G>C p.S90T | Missense Mutation (SNP) | VAF 108/377 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99418582; called by muse, mutect2, varscan2
- UMOD | c.1823-1G>T p.X608_splice | Splice Site (SNP) | VAF 65/206 reads (32%) | catalogued as COSV100208686; called by muse, mutect2, varscan2
- USP6 | c.526T>G p.Y176D | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100004873; called by muse, mutect2, varscan2
- VPS13B | c.5777G>A p.R1926K | Missense Mutation (SNP) | VAF 306/1320 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV100663569; called by muse, mutect2, varscan2
- WASHC5 | c.1949T>C p.I650T | Missense Mutation (SNP) | VAF 348/1350 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV100573066; called by muse, mutect2, varscan2
- ZAN | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100770316; called by muse, mutect2
- ZC4H2 | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 153/375 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as COSV100565214; called by muse, mutect2, varscan2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 20/172 reads (12%) | catalogued as rs761578656; called by mutect2, varscan2
- ZNF281 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as rs1287186414, COSV99664518; called by muse, mutect2, varscan2
- ZNF680 | c.811T>C p.C271R | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100549333; called by muse, mutect2, varscan2
- ZNF74 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100677557; called by muse, mutect2, varscan2
- CFAP36 | c.494_495del p.K165Rfs*4 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.4101_4122del p.P1368Afs*32 | Frame Shift Del (DEL) | VAF 44/202 reads (22%) | called by mutect2, pindel, varscan2
- GAL3ST4 | c.1121_1129del p.N374_L377delinsI | In Frame Del (DEL) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- ILKAP | c.848_864del p.V283Gfs*30 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- LILRA4 | c.309_327del p.G105Tfs*7 | Frame Shift Del (DEL) | VAF 36/98 reads (37%) | called by mutect2, varscan2
- RALGPS2 | c.388-1_413del p.X130_splice | Splice Site (DEL) | VAF 42/310 reads (14%) | called by mutect2, pindel
- SLU7 | c.1465-18_1470del p.X489_splice | Splice Site (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel
- CDH6 | c.1761G>A p.R587= | Silent (SNP) | VAF 120/489 reads (25%) | catalogued as COSV99419740; called by muse, mutect2, varscan2
- CUX1 | c.2553G>A p.E851= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99473030; called by muse, mutect2, varscan2
- DNAH5 | c.11181A>G p.L3727= | Silent (SNP) | VAF 282/2888 reads (10%) | catalogued as COSV99454075; called by muse, mutect2
- FRMPD2 | c.3666T>A p.G1222= | Silent (SNP) | VAF 174/509 reads (34%) | catalogued as COSV100564174; called by mutect2, varscan2
- GLP2R | c.1335T>A p.A445= | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as COSV99302475; called by muse, mutect2, varscan2
- GRM6 | c.1176C>T p.D392= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV51445284; called by muse, mutect2, varscan2
- HCN1 | c.2508G>A p.P836= | Silent (SNP) | VAF 90/113 reads (80%) | catalogued as COSV57495249; called by muse, mutect2, varscan2
- KPNA6 | c.531T>C p.N177= | Silent (SNP) | VAF 243/686 reads (35%) | catalogued as COSV101012616; called by muse, mutect2, varscan2
- MYO10 | c.3672G>A p.G1224= | Silent (SNP) | VAF 144/974 reads (15%) | catalogued as rs765901568, COSV99946268; called by mutect2, varscan2
- PCDHGA3 | c.246C>T p.G82= | Silent (SNP) | VAF 46/71 reads (65%) | catalogued as COSV99546634; called by muse, mutect2, varscan2
- PDE4D | c.528A>G p.L176= (on ENST00000340635 / NM_001104631.2; = p.L40= on NM_006203.4) | Silent (SNP) | VAF 58/97 reads (60%) | catalogued as COSV100509010; called by muse, mutect2, varscan2
- PXDNL | c.2523T>C p.P841= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100686274; called by muse, mutect2
- SBF2 | c.1722T>G p.A574= | Silent (SNP) | VAF 256/903 reads (28%) | catalogued as COSV99815696; called by muse, mutect2, varscan2
- SLC6A7 | c.762G>C p.L254= | Silent (SNP) | VAF 120/379 reads (32%) | catalogued as COSV100046560; called by muse, mutect2, varscan2
- UROC1 | c.1818C>A p.G606= | Silent (SNP) | VAF 6/161 reads (4%) | catalogued as COSV99332365; called by muse, mutect2
- VWA3A | c.3324C>A p.G1108= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs939721636, COSV100241310, COSV100241418; called by muse, mutect2, varscan2
- ZFHX4 | c.1974C>A p.T658= | Silent (SNP) | VAF 104/246 reads (42%) | catalogued as COSV99267444; called by muse, mutect2, varscan2
- C15orf54 | n.411C>T | RNA (SNP) | VAF 472/1159 reads (41%) | called by muse, mutect2, varscan2
- LINC00303 | n.373G>C | RNA (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- RN7SL106P | chr15:23167218 C>T | 3'Flank (SNP) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- SMPDL3B | c.1005+101A>T | Intron (SNP) | VAF 80/140 reads (57%) | catalogued as COSV100874610; called by muse, mutect2, varscan2
